Somatic mutation profile of tumor specimen TCGA-TM-A7C4-01A (aliquot TCGA-TM-A7C4-01A-11D-A32B-08) from TCGA case TCGA-TM-A7C4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.0 years (14,603 days).
Specimen TCGA-TM-A7C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8496ee54-9f42-4a86-8f2e-284a3811bad5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A7C4-10A (Blood Derived Normal), aliquot TCGA-TM-A7C4-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dae120b-2ff0-4e23-8be1-1b738a9cb947

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.823T>G p.C275G | Missense Mutation (SNP) | VAF 20/34 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52700773, COSV52771673; called by muse, mutect2, varscan2
- AGL | c.2870G>A p.C957Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99649766; called by muse, mutect2, varscan2
- ATRX | c.662+1G>A p.X221_splice | Splice Site (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100971211; called by muse, mutect2, varscan2
- CCDC9 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1401160841, COSV99699788; called by muse, mutect2, varscan2
- CDKL5 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV66111861, COSV66113856; called by muse, mutect2, varscan2
- CLCN5 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100260312; called by muse, mutect2, varscan2
- COPB1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99999796; called by muse, mutect2, varscan2
- HACE1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV99494103; called by muse, mutect2, varscan2
- ILDR1 | c.1343G>A p.R448H (on ENST00000344209 / NM_001199799.2; = p.R404H on NM_175924.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs753781354, COSV99878703; called by muse, varscan2
- LCT | c.4797C>A p.S1599R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV99930077; called by muse, mutect2, varscan2
- LRRC32 | c.692A>C p.E231A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99477150; called by muse, mutect2, varscan2
- MYH8 | c.4195C>T p.R1399C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs924415460, COSV67968369; called by muse, mutect2, varscan2
- NHS | c.4787T>C p.V1596A | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.668); catalogued as COSV101196847; called by muse, mutect2, varscan2
- OR4D6 | c.629G>T p.W210L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs202119522; called by muse, mutect2, varscan2
- OR5W2 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV100747699, COSV100747795; called by muse, mutect2, varscan2
- PTPRB | c.3413G>C p.S1138T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99716491, COSV99718365; called by muse, mutect2, varscan2
- PTPRG | c.3967G>C p.D1323H | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99876275; called by muse, mutect2
- RASA2 | c.954C>G p.D318E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53945578, COSV99656567; called by muse, mutect2, varscan2
- REL | c.1747A>T p.S583C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.43); catalogued as COSV99692270; called by muse, mutect2, varscan2
- RPS6KA6 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.055); catalogued as COSV53117151, COSV99425179; called by muse, mutect2, varscan2
- TP53TG5 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs780299271, COSV101022354, COSV65577436; called by muse, mutect2, varscan2
- TTN | c.46581G>A p.W15527* (on ENST00000591111; = p.W8103* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 48/181 reads (27%) | catalogued as COSV100623053; called by muse, mutect2, varscan2
- USF3 | c.3076A>T p.M1026L | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.009); catalogued as COSV100325612; called by muse, mutect2
- ZNF101 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs558462983, COSV58908860; called by muse, mutect2, varscan2
- FMNL3 | c.1187_1221+1del p.X396_splice | Splice Site (DEL) | VAF 22/194 reads (11%) | called by mutect2, pindel
- ADCY10 | c.3489A>C p.R1163= | Silent (SNP) | VAF 129/333 reads (39%) | catalogued as COSV100896999; called by muse, mutect2, varscan2
- ATRX | c.3816C>A p.A1272= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100971209; called by muse, mutect2, varscan2
- CARS2 | c.1371T>C p.F457= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99959875; called by muse, mutect2, varscan2
- NOTCH3 | c.4695C>T p.S1565= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99658220; called by muse, mutect2, varscan2
- PPP1R26 | c.2592C>T p.T864= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs942899516, COSV63356055; called by muse, mutect2
- SLC22A5 | c.459G>A p.V153= | Silent (SNP) | VAF 96/276 reads (35%) | catalogued as COSV99810093; called by muse, mutect2, varscan2
